TCGA case TCGA-CJ-4900 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33cd8b05-2b9b-40dd-97a2-40d02e27ee90

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 1,714 days (4.7 years).

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 69.8 years (25,508 days); Year of diagnosis: 2006; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 14.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Neoadjuvant; Days to treatment start: -92 days; Days to treatment end: 0 days; Number of cycles: 3; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Treatment intent type: Neoadjuvant; Days to treatment start: -92 days; Days to treatment end: 0 days; Number of cycles: 3; Route of administration: Intravenous / Oral.

Follow-up (2 entries)
- Days to follow up: 1,714 days (4.7 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Recurrence/Progression.

Molecular and laboratory tests
- Hemoglobin: Low.
- Calcium: Elevated.
- Platelets: Elevated.
- Leukocytes: Elevated.
- Lactate Dehydrogenase: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4900-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 3; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-CJ-4900-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 30.
  Slide TCGA-CJ-4900-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30.
- Sample TCGA-CJ-4900-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4900-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.4; Intermediate dimension: 1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Tarceva; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Neo-Adjuvant.
- Drug treatment 1, Route of administrations: Route of administration: IV; Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Neo-adjuvant.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: At Recurrence/Progression Of Disease.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject Positive for Neo-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,714 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,714 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,714 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-4900-01A-01D-1331-01): tumor purity 0.47, ploidy 1.94, whole-genome doublings 0.
